Somatic mutation profile of tumor specimen TCGA-CV-7243-01A (aliquot TCGA-CV-7243-01A-11D-2012-08) from TCGA case TCGA-CV-7243, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.6 years (18,466 days).
Specimen TCGA-CV-7243-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59d70c56-5be9-43fa-9a0d-8e2122587f32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7243-10A (Blood Derived Normal), aliquot TCGA-CV-7243-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5fe1485-f709-4f51-accb-f0acbfd09129

The open-access MAF lists 71 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 17, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.464_484del p.T155_A161del | In Frame Del (DEL) | VAF 17/55 reads (31%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AAR2 | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100299314; called by muse, mutect2
- ADGRG4 | c.8741G>A p.C2914Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54961928, COSV99795616; called by muse, mutect2, varscan2
- AP5M1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV55106599, COSV99841224; called by muse, mutect2, varscan2
- APPL2 | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0.052); catalogued as rs183791204; called by muse, mutect2, varscan2
- ARHGEF12 | c.3554C>G p.S1185C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV100754943; called by muse, mutect2, varscan2
- BICRA | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs775371257, COSV101194336; called by muse, mutect2, varscan2
- CCDC88A | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV55061795, COSV99710448; called by muse, mutect2, varscan2
- CNTNAP1 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs768384591, COSV99226483; called by muse, mutect2, varscan2
- ELAC1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1198371933, COSV53996152, COSV99494928; called by muse, mutect2, varscan2
- EPG5 | c.5057G>A p.R1686H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs375463159, COSV56352354; called by muse, mutect2, varscan2
- GCN1 | c.5072C>T p.S1691L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1474267172, COSV56109128; called by muse, mutect2, varscan2
- H2BC12 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.165); catalogued as COSV100804682; called by muse, mutect2
- HPS4 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs530118832, COSV100404789, COSV61104444; called by muse, mutect2, varscan2
- IKBKB | c.1154A>T p.D385V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as COSV100645707; called by muse, mutect2, varscan2
- IL17RB | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as rs145364776, COSV55472399; called by muse, mutect2, varscan2
- KIAA0586 | c.923T>C p.L308S (on ENST00000619416 / NM_001244190.2; = p.L323S on NM_014749.5) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as rs563531719, COSV99708194; called by muse, varscan2
- KMT2B | c.6016G>T p.E2006* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV55857905, COSV55864123; called by muse, mutect2
- MMP15 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1292972984, COSV54679954; called by muse, mutect2, varscan2
- MTSS2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs149700961; called by muse, mutect2, varscan2
- MUC16 | c.2963C>A p.S988Y | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV101200023; called by muse, mutect2, varscan2
- NR3C2 | c.1379T>A p.F460Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100679127; called by muse, mutect2, varscan2
- OBSL1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779820021, COSV54723153; called by muse, mutect2, varscan2
- OR5AR1 | c.525T>G p.N175K | Missense Mutation (SNP) | VAF 41/303 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs773642545, COSV100265669, COSV100265855; called by muse, mutect2, varscan2
- OR5H15 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 115/353 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62949089; called by muse, mutect2, varscan2
- OR6Q1 | c.419T>G p.V140G | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100110013; called by muse, varscan2
- PAPPA2 | c.2246G>T p.S749I | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100866805, COSV62784579; called by muse, mutect2, varscan2
- PAX1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68273123; called by muse, mutect2, varscan2
- PCLO | c.5430C>A p.D1810E | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV61658080; called by muse, mutect2, varscan2
- PKD1 | c.6721C>G p.L2241V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574203747, COSV99238218; called by muse, mutect2, varscan2
- PSG8 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.274); catalogued as rs769407964, COSV100126120; called by muse, mutect2, varscan2
- PTPRM | c.3635G>A p.R1212Q | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1020421872, COSV100155194, COSV100157544; called by muse, mutect2, varscan2
- RASA1 | c.2366G>T p.R789L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57196517, COSV57198182, COSV99169866; called by muse, mutect2, varscan2
- RSRC2 | c.531G>T p.R177S | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.943); catalogued as COSV100063604, COSV59203878, COSV59204805; called by muse, mutect2, varscan2
- SIRPB1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1336637312, COSV53538460, COSV53539442; called by muse, mutect2, varscan2
- SMG8 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs1435323813, COSV56285567, COSV99958850; called by muse, mutect2, varscan2
- STAB2 | c.2612G>T p.C871F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101185992; called by muse, mutect2, varscan2
- STYXL1 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs147059565; called by muse, mutect2, varscan2
- TMEM59L | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99450253; called by muse, mutect2
- TPH2 | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.034); catalogued as COSV100422104; called by muse, mutect2
- TRIML2 | c.1058G>T p.W353L | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100456079; called by muse, mutect2, varscan2
- TRPV4 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368937671; called by muse, mutect2, varscan2
- UTRN | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as COSV62328334; called by muse, mutect2, varscan2
- VPS13D | c.10546C>T p.P3516S | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764394669, COSV99166800; called by muse, mutect2, varscan2
- ZNF329 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs368309022; called by muse, mutect2, varscan2
- ZNF512 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV62675655; called by muse, mutect2, varscan2
- ZNF610 | c.1246A>T p.T416S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100016859; called by muse, mutect2, varscan2
- DDX52 | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- EEA1 | c.2096_2100del p.D699Afs*12 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by pindel, varscan2
- NOTCH1 | c.4055_4068del p.C1352Lfs*48 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- TKTL1 | c.94_95dup p.I33Efs*34 | Frame Shift Ins (INS) | VAF 25/147 reads (17%) | called by mutect2, pindel, varscan2
- TM9SF2 | c.1500_1503del p.H500Qfs*43 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | called by mutect2, pindel, varscan2
- ALDH16A1 | c.315G>A p.L105= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV99512939; called by muse, mutect2, varscan2
- BAX | c.90C>T p.F30= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99509101; called by muse, mutect2, varscan2
- CACNA1A | c.3612G>A p.E1204= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV100802510; called by muse, mutect2, varscan2
- CACNG7 | c.34C>T p.L12= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99712057; called by muse, mutect2, varscan2
- DPP6 | c.2334G>A p.A778= (on ENST00000377770 / NM_001364500.2; = p.A716= on NM_001936.5) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs766943750, COSV100125845, COSV100126911; called by mutect2, varscan2
- ERVW-1 | c.516C>T p.L172= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV101423844; called by muse, mutect2, varscan2
- HIVEP2 | c.3204G>A p.T1068= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs755030077, COSV50008534, COSV99173603; called by muse, mutect2, varscan2
- MAP1A | c.7104C>T p.N2368= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs561219457, COSV100288705; called by muse, mutect2, varscan2
- NDNF | c.393T>C p.N131= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs1485126896, COSV101113182; called by muse, mutect2, varscan2
- NOCT | c.534C>T p.L178= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV99763868; called by muse, mutect2, varscan2
- PCDH10 | c.1116G>A p.A372= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV99993655; called by muse, mutect2, varscan2
- PLEKHJ1 | c.276C>T p.S92= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs781527052, COSV55553997, COSV99677855; called by muse, mutect2, varscan2
- RYR1 | c.5988C>T p.R1996= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs193922787, COSV62097239; ClinVar: not provided; called by muse, mutect2, varscan2
- SF3B3 | c.2406G>A p.T802= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs760246368, COSV100209947; called by muse, mutect2, varscan2
- SLC6A6 | c.666C>T p.L222= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs1283307219, COSV100692189, COSV62649549; called by muse, mutect2, varscan2
- SOX11 | c.268C>T p.L90= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV100431153; called by muse, mutect2, varscan2
- UCHL1 | c.516C>T p.L172= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs763513865, COSV99449132; called by muse, mutect2, varscan2
- CHD6 | c.-23-12708C>G | Intron (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100498312; called by muse, mutect2, varscan2
